Surgical pathology report (de-identified scan), TCGA case TCGA-CC-A5UC, project TCGA-LIHC (Liver Hepatocellular Carcinoma), tissue source site ILSBio, specimen TCGA-CC-A5UC-01A (Primary Tumor).

[page 1 of 5]
Clinical Case Report

(For Collection of Cancerous Tissue)

ICD-O-3
Carcinoma, Hepatic Adenoma^{N0}
8170/3
Path Carcinoma, Hepatic Adenoma,
solid type 8170/3
Site: Liver, Hepatic NOS
C22.0
JW 4/2/13

Informed Consent

I personally informed this patient that a specimen(s) would be collected to be used for research purposes. I reviewed the **RESEARCH SUBJECT INFORMATION AND CONSENT FORM** with the patient and answered any questions the patient had. The patient then signed the consent form as a free and voluntary act. A copy of this informed consent document will be retained at our institution.

Name of Physician or Study Coordinator

Signature

Date

Clinical Information

GENERAL INFORMATION				
Date of Birth (mm/dd/yyyy)	Height	Marital Status	Race	Temperature
	1m65	☐ Single ☒ Married	Vietnamese	
Gender	Weight	☐ Divorced ☐ Widow	Blood Pressure	Heart Rate
☒ Male ☐ Female	57kg		13/8	

HISTORY OF PRESENT ILLNESS
Chief Complaints: Abdominal pain; fever;
Symptoms: Weakness; weight loss
Clinical Findings:
Performance Scale (Karnofsky Score): ☐ 100 Asymptomatic ☐ 80-90 Symptomatic but Fully Ambulatory ☒ 60-70 Symptomatic, in bed less than 50% of day ☐ 40-50 Symptomatic, in bed more than 50% of day, but not bed ridden ☐ 20-30 Bed Ridden

CURRENT MEDICATIONS				
Drug	Dose	Route	Frequency	Date (mm/dd/yyyy)
				/ / To / /
				/ / To / /
				/ / To / /
				/ / To / /
				/ / To / /

[page 2 of 5]
PAST MEDICAL HISTORY			
Diagnosis/Disease/Disorder/Injury	Diagnosis Date	Treatment	Status

OB/GYN HISTORY		
Menopausal Status	Date of First Menses	# of Pregnancies
☐ Pre-menopausal		
☐ Peri-Menopausal	Date of Last Menses	# of Live Births
☐ Post-menopausal		
Birth Control: ☐ Condom ☐ Oral Contraceptive ☐ IUD ☐ Other: _____		☐ Hormone Replacement Therapy: _____

SOCIAL HISTORY				
Occupation:		Environmental Hazards:		
Smoking History				
Current Status	TYPE	Packs/day	Duration	When Quit
☐ YES ☒ NO			(yrs)	(yr)
Alcohol Consumption				
Current Status	TYPE	Drinks/day	Duration	When Quit
☒ YES ☐ NO		2 drinks/day	3 (1) yrs	3 months ago (yr)
Drug Use				
Current Status	TYPE	Frequency	Duration	When Quit
☐ YES ☒ NO			(yrs)	(yr)

FAMILY MEDICAL HISTORY		
Relative	Diagnosis	Age of Diagnosis

LAB DATA					
Test	Result	Date	Test	Result	Date
HIV	☒ Negative ☐ Positive: _____		CEA	☐ Negative ☐ Positive: _____	
Hep B	☒ Negative ☐ Positive: _____		CA 15-3	☐ Negative ☐ Positive: _____	
Hep C	☒ Negative ☐ Positive: _____		CA 19-9	☐ Negative ☐ Positive: _____	
AFP	☐ Negative ☐ Positive: _____		PSA	☐ Negative ☐ Positive: _____	
Other:	☐ Negative ☐ Positive: _____		Other:	☐ Negative ☐ Positive: _____	
B/T Cell Markers:					

[page 3 of 5]
DIAGNOSTIC STUDIES		
Study	Results	Date
Ultrasound	A tumor was found in the liver	
X-Ray		
CT		
Endoscopy		
MRI		
Biopsy		

CLINICAL DIAGNOSIS	
Preoperative Clinical Diagnosis	
Liver Cancer	
Location of Suspected Involved Lymph Nodes	Location of Suspected Distant Metastasis
Clinical Staging	Date of Diagnosis
T ₃ N ₀ M ₀ Stage: IIIA	

Treatment Information

SURGICAL TREATMENT		
Procedure	Date of Procedure	
Resection of the right liver		
Primary Tumor		
Organ	Detailed Location	Size
Liver Tumor	Right Liver	8 x 7 x 5 cm
Extension of Tumor		
Lymph Nodes		
Description	Location of Lymph Nodes	# of Lymph Nodes
Palpable, Non-Dissected Lymph Nodes		
Dissected Lymph Nodes		
Distant Metastasis		
Organ	Detailed Location	Size
Surgical Staging		
T ₃ N ₀ M ₀ Stage: IIIA		

NEOADJUVANT THERAPY (Chemo, Radiation, Immuno, Hormonal, or Molecular)				
Drug/Treatment	Dose	Route	Frequency	Date (mm/dd/yyyy)
				/ / To / /
				/ / To / /
				/ / To / /
				/ / To / /
				/ / To / /

[page 4 of 5]
Pathology Form

Specimen Information

Collected by: _

___ Date: _

Time: _

Preserved by: _

___ Date: _

Time: _

SPECIMEN TYPE (# of samples provided)							
Frozen		Paraffin Block		Blood/Serum/Plasma		Slide	
Diseased	Normal	Diseased	Normal	Diseased	Normal	Diseased	Normal
4	2	4	2			4	2
Time to LN2		Time to Formalin		Time to LN2			
12 min		13 min					

PATHOLOGICAL DESCRIPTION			
Primary Tumor			
Organ	Size	Extension of Tumor	Distance to NAT
Liver Tumor	8 x 7 x 5 cm	Right liver	6 cm
Lymph Nodes			
Location	# Examined	# Metastasized	
Distant Metastasis			
Organ	Detailed Location	Size	
Pathological Staging			
pT 3 N 0 M 0 Stage: IIIA			
Notes:			

[page 5 of 5]
Consolidated Pathology Diagnosis

Histological Pattern											
Cell Distribution			+ -		Structural Pattern			+ -			
Diffuse					Streaming						
Mosaic			✓		Storiform						
Necrosis				✓	Fibrosis						
Lymphocytic Infiltration			α		Palisading						
Vascular Invasion				✓	Cystic Degeneration						
Clusterized			α		Bleeding						
Alveolar Formation				α	Myxoid Change						
Indian File				α	Psammoma/Calcification						

Cellular Differentiation															
Squamous		+ -		Adenomatous		+ -		Sarcomatous		+ -		Lymphomatous		+ -	
Squamoid Cell				Glandular cell				Round Cell				Large Cell			
Spindle Cell				Cell Stratification				Fibroblast				Small Cell			
Keratin				Secretion				Osteoblast				RS Cell/RS Like			
Desmosome				Intracyt. Vacuole				Lipoblast				Inflam. Cell			
Pearl				Gland formation				Myoblast				Plasma Cell			

Cellular Differentiation: ☐ Well ☐ Moderate ☒ Poor

Nuclear Appearance				
Nuclear Atypia:	0	I	II	III
Aniso Nucleosis				✓
Hyperchromatism				✓
Nucleolar Prominent				✓
Multinucleated Giant Cell				✓
Mitotic Activity				✓

Nuclear Grade: α

D₁ 75% D₂ 75% D₃ 60% D₄ 75%

Final Pathology Report

Histological Diagnosis: Hepatocellular Carcinoma **Grade:** 3
Solid type, ~~poorly differentiated~~

Comments:

Director, Research Pathology

Date

Source: NCI Genomic Data Commons file 6a456bfa-a4ff-4bd6-991c-a609eb7d321e (TCGA-CC-A5UC.21B4A68D-F76C-49BB-81D7-423E957852E1.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).